Somatic mutation profile of tumor specimen TCGA-G3-AAV2-01A (aliquot TCGA-G3-AAV2-01A-11D-A36X-10) from TCGA case TCGA-G3-AAV2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 50.3 years (18,363 days).
Specimen TCGA-G3-AAV2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) accce6b5-964e-4dec-bb52-af82c9805484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV2-10A (Blood Derived Normal), aliquot TCGA-G3-AAV2-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c9074d7-9029-4056-ab97-92e7418a0aad

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Nonsense Mutation 2, Splice Site 2, In Frame Del 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 105/180 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.3737T>A p.L1246H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100966371; called by muse, mutect2, varscan2
- ACAP2 | c.1476A>T p.Q492H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.738); catalogued as COSV100461395; called by muse, mutect2, varscan2
- ACTL7A | c.1250T>A p.V417D | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100453028; called by muse, mutect2, varscan2
- ADAMTS20 | c.4096A>T p.N1366Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV101166051; called by muse, mutect2, varscan2
- AHNAK | c.10568A>T p.E3523V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99945405; called by muse, mutect2, varscan2
- ARFGEF2 | c.1907A>G p.Q636R | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as COSV100903955; called by muse, mutect2, varscan2
- C3 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs1358823675, COSV99835986; called by muse, mutect2, varscan2
- CACNA2D3 | c.2275A>T p.N759Y | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99869814; called by muse, mutect2
- CDHR2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.053); catalogued as COSV56136683, COSV99990961; called by muse, mutect2, varscan2
- CISH | c.562A>G p.K188E (on ENST00000348721 / NM_145071.4; = p.K205E on NM_013324.6) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.214); catalogued as COSV100811707; called by muse, mutect2, varscan2
- CNST | c.1753T>A p.S585T | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100829985; called by muse, mutect2, varscan2
- CTR9 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV100797243; called by muse, mutect2, varscan2
- CTRC | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | catalogued as rs1428850483, COSV101036274, COSV65621435; called by muse, mutect2, varscan2
- EP300 | c.4525T>A p.W1509R | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607220, COSV99610081; called by muse, mutect2, varscan2
- FLVCR1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV100757888; called by muse, mutect2, varscan2
- HS3ST5 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as rs374141405; called by muse, mutect2, varscan2
- KCNA4 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.622); catalogued as rs1364807757, COSV100068955, COSV60252205; called by muse, mutect2, varscan2
- LAMA2 | c.4360G>C p.G1454R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101369902; called by muse, mutect2, varscan2
- LONP2 | c.2351A>C p.K784T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99588787; called by muse, mutect2, varscan2
- MAP7 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100643713; called by muse, mutect2, varscan2
- MCC | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.022); catalogued as COSV101342709; called by muse, mutect2, varscan2
- MED13L | c.2345-2A>G p.X782_splice | Splice Site (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99927735; called by muse, mutect2, varscan2
- MKNK2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99170213; called by muse, mutect2, varscan2
- MKNK2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51735539, COSV99170214; called by muse, mutect2, varscan2
- NBPF1 | c.2048G>C p.G683A | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV99844024; called by muse, varscan2
- NDN | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV59358784, COSV59359838; called by muse, mutect2, varscan2
- OR2B3 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV101013746; called by muse, mutect2, varscan2
- OR5H1 | c.281T>A p.L94H | Missense Mutation (SNP) | VAF 98/249 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100641614; called by muse, mutect2, varscan2
- PFN4 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.241); catalogued as COSV100500349; called by muse, mutect2, varscan2
- PRR12 | c.56C>T p.P19L (on ENST00000615927; = p.P840L on NM_020719.3) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.154); catalogued as COSV101330547; called by muse, mutect2, varscan2
- PSMB11 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV101273402; called by muse, mutect2, varscan2
- RLN3 | c.164C>A p.S55* | Nonsense Mutation (SNP) | VAF 55/130 reads (42%) | catalogued as COSV99651888; called by muse, mutect2, varscan2
- ROCK1 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101296217; called by muse, mutect2, varscan2
- SLC9C1 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs201512353, COSV59890424; called by muse, mutect2, varscan2
- TAS1R3 | c.80A>C p.Q27P | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV100229235; called by muse, mutect2, varscan2
- USP29 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99517604; called by muse, mutect2, varscan2
- MED8 | c.411_411+36del p.X137_splice | Splice Site (DEL) | VAF 35/71 reads (49%) | called by mutect2, pindel
- METTL21C | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- PPP1R10 | c.675_677del p.K225del | In Frame Del (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2
- TKFC | c.793_795del p.M265del | In Frame Del (DEL) | VAF 26/74 reads (35%) | called by pindel, varscan2
- ADGRL2 | c.3312C>T p.C1104= (on ENST00000370717 / NM_001366005.1; = p.C1091= on NM_012302.4) | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as rs879246111, COSV99586950; called by muse, mutect2, varscan2
- ASPHD1 | c.870C>T p.A290= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs374797206; called by muse, mutect2, varscan2
- CHST3 | c.1158C>T p.Y386= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs1362906854, COSV64151062; called by muse, mutect2, varscan2
- EFCAB6 | c.3214C>T p.L1072= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV99412342; called by muse, mutect2, varscan2
- GARNL3 | c.2217A>G p.Q739= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs62579716, COSV100149872; called by muse, mutect2, varscan2
- NTN3 | c.855C>T p.C285= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs745543860, COSV99564637; called by muse, mutect2, varscan2
- PLXNA4 | c.1110G>T p.R370= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100322267; called by muse, mutect2, varscan2
- TTN | c.88173T>C p.S29391= (on ENST00000591111; = p.S21967= on NM_003319.4) | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV100592606; called by muse, mutect2, varscan2
- VSIG8 | c.762G>C p.V254= | Silent (SNP) | VAF 109/145 reads (75%) | catalogued as COSV100928747; called by muse, mutect2, varscan2
- ZMAT1 | c.717G>A p.K239= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as rs1379750988, COSV100858658, COSV65658225; called by muse, mutect2, varscan2
- ZNF687 | c.1623C>T p.A541= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV99649260; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33867G>A | Intron (SNP) | VAF 18/39 reads (46%) | catalogued as COSV57764940; called by muse, varscan2
- GPR174 | c.-2T>G | 5'UTR (SNP) | VAF 82/202 reads (41%) | catalogued as COSV99337937; called by mutect2, varscan2
- NDUFV3 | c.170-4852C>T | Intron (SNP) | VAF 46/63 reads (73%) | catalogued as COSV100446866; called by muse, mutect2, varscan2
